Surgical pathology report (de-identified scan), TCGA case TCGA-EO-A1Y8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University Health Network, specimen TCGA-EO-A1Y8-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3
carcinoma, serous, NOS 8441/3
Site: endometrium C54.1
3/6/11 *hw*

Surgical Pathology Consultation Report

Patient
Name:
MRN:
DOB:
Gender:
HCN:
Ordering
MD:
Copy To:

Service:
Visit #:
Location:
Facility:

Accession #:
Collected:
Received:
Reported:

Specimen(s) Received

1. Pelvic: Right pelvic lymph node
2. Lymph node: Right common iliac lymph node
3. Lymph node: Left pelvic node
4. Uterus: Uterus, cervix, right ovary & tube & left tube
5. Omentum biopsy

Diagnosis

1. Right pelvic lymph node, lymphadenectomy:
- Eight lymph nodes, negative for malignancy (0/8)
2. Right common iliac lymph node, lymphadenectomy:
- Three lymph nodes negative for malignancy (0/3)
3. Left pelvic lymph node, lymphadenectomy
- Five lymph nodes negative for malignancy (0/5)
4. Uterus, cervix bilateral fallopian tubes and ovaries, hysterectomy, bilateral salpingectomy, right oophorectomy:
Endometrium:
- SEROUS CARCINOMA

Myometrium:
- Invaded by adenocarcinoma, confined to the inner half
- No lymphovascular invasion identified

Cervix:

- No histological abnormality.

Right & left ovaries:

- No histological abnormality.

Right & left fallopian tubes

- Paratubal cysts.

5. Omentum, biopsy:

- Negative for malignancy

Reviewed: KMI		

[page 2 of 3]
Synoptic Data

Specimen:	Uterine corpus Cervix Right ovary Right fallopian tube Left fallopian tube Omentum
Procedure:	Simple hysterectomy Bilateral salpingo-oophorectomy Omentectomy
Lymph Node Sampling:	Performed: Pelvic lymph nodes
Specimen Integrity:	Intact hysterectomy specimen
Tumor Site:	Anterior endometrium
Tumor Size:	Greatest dimension: 3 cm Additional dimension: 2.8 cm Additional dimension: 1.6 cm
Histologic Type:	Serous adenocarcinoma
Histologic Grade:	Not applicable
Myometrial Invasion:	Present Myometrial thickness: 13 mm Less than 50% myometrial invasion
Involvement of Cervix:	Not involved
Extent of Involvement of Other Organs:	Right ovary not involved Left ovary not involved Right fallopian tube not involved Left fallopian tube not involved Omentum not involved
Margins:	Uninvolved by invasive carcinoma
Lymph-Vascular Invasion:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT1b (IB): Tumor invades more than or one-half of the myometrium
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Pelvic lymph nodes examined: 16 Pelvic lymph nodes involved: 0 Para-aortic lymph nodes examined: 0 Para-aortic lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None identified

Comment

Tumor cells have characteristic features of serous carcinoma. Clear cell changes is also seen in some areas, however the tumor cells are diffusely positive for p53 and p16. Focal glands are positive for ER but the tumor is negative for PR and PASD consistent with serous carcinoma.

Electronically verified

by:

MD

Clinical History

endometrial ca.

Gross Description

1. The specimen container labelled with the patient's name and as "right pelvic lymph nodes" contains multiple pieces of an unoriented fibroadipose tissue measuring from 0.8 x 0.6 x 0.6 to 3.8 x 2.3 x 1.4

[page 3 of 3]
received in 10% buffered formalin. . Within the fatty tissue, multiple lymph nodes are identified grossly measuring 0.3 x 0.2 x 0.2 to 1.4 x 1.2 x 1.0 cm.

The specimen is submitted in toto as follows:

- 1A one lymph node bisected
- 1B one lymph node bisected
- 1C one lymph node bisected
- 1D multiple lymph nodes.
- 1E 1F the rest of the fatty tissue submitted in toto

2. The specimen container labelled with the patient's name and as "right common iliac lymph nodes" contains a single piece of an unoriented fibroadipose tissue measuring 2.0 x 1.3 x 0.6 received in 10% buffered formalin. . Within the fatty tissue, two lymph nodes are identified grossly measuring 0.5 x 0.4 x 0.4 and 1.6 x 0.5 x 0.5 cm

The specimen is submitted in toto as follows:

- 2A two lymph nodes
- 2B the rest of the fatty tissue submitted in toto

3. The specimen container labelled with the patient's name and as "left pelvic lymph nodes" contains multiple pieces of an unoriented fibroadipose tissue measuring 1.0 x 0.9 x 0.8 to 1.8 x 1.3 x 1.5 received in 10% buffered formalin. . Within the fatty tissue, multiple lymph nodes are identified grossly measuring 0.4 x 0.4 x 0.4 to 1.3 x 0.6 x 0.6 cm.

The specimen is submitted in toto as follows:

- 3A multiple lymph nodes.
- 3B one lymph node bisected
- 3C one lymph node bisected
- 3D-3E the rest of the fatty tissue submitted in toto

4. The specimen container is labeled with the patient's name and as "uterus, cervix, right ovary and bilateral fallopian tubes" contains a uterus, cervix, right ovary, right and left fimbriated fallopian tubes received in 10% buffered formalin. The entire specimen weighs 38.3 g. The uterus measures 6.0 SI x 4.4 ML x 5.5 cm AP with the cervix measuring 2.7 cm with a 0.4 cm ovoid-shaped os. The right and left fimbriated fallopian tubes measure 6.0 x 0.4 and 4.2 x 0.5 cm respectively. The right ovary measures 3.6 x 1.0 x 0.8 cm. On gross examination, multiple paratubal cysts are identified on both the right and left fimbriated fallopian tube ranging in size from 0.2 x 0.2 x 0.2 cm to 0.6 x 0.6 x 0.4 cm filled with clear fluid as well as and gelatinous material. The external surface of the right ovary as well as the cut surface is tan in color, smooth and grossly unremarkable. The anterior and posterior uterine serosa is intact, brown-tan in color smooth and shiny. On sectioning, a large polypoid tumor is identified on the superior aspect of the anterior and posterior endometrium measuring 2.8 x 3.0 x 1.6 cm. The tumor is brown tan in color, and has a soft and slightly friable consistency. The rest of the endometrium is tan in color shiny and smooth. The myometrium measures 0.6 cm in thickness and has a slightly trabeculated appearance. The endocervix is tan in color, and appears to be slightly nodular. Multiple pinpoint hemorrhages are identified on the exocervix. Representative sections are submitted as follows:

- 4A left fimbria longitudinally sectioned and submitted in toto
- 4B left fallopian tube serially sectioned and submitted in toto
- 4C right fimbriated longitudinally sectioned and submitted in toto
- 4D. right fallopian tube serially sectioned and submitted in toto
- 4E 4G right ovary serially sectioned and submitted in toto
- 4H anterior endomyometrium superior aspect full thickness
- 4I-4J anterior endomyometrium mid superior aspect to cervix longitudinal section
- 4K posterior endomyometrium superior aspect thickness
- 4L-4M posterior endomyometrium superior aspect to cervix longitudinal section
- multiple pieces of tissue stored frozen

5. The specimen container is labeled with the patient's name and as "omentum" contains a single piece of an unoriented fibroadipose tissue received in 10% buffered formalin. The tissue measures 8.0 x 1.8 x 1.5 cm.

On serial sectioning, the cut surface is predominantly fatty with no nodules identified grossly.

Representative sections are submitted as follows:

- 5A- 5E representative section submitted

Source: NCI Genomic Data Commons file fcc506fd-afd5-43ac-a7fa-4b7587e7ecdf (TCGA-EO-A1Y8.61143E14-52BD-499F-901C-4BD1EA83DAC1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).